Gene-level copy-number profile of tumor specimen ALCH-B2C6-TTP1-A from ALCHEMIST case ALCH-B2C6, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 69.7 years (25,463 days).
Specimen ALCH-B2C6-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e9b1ffaf-9bfc-4941-96ca-4928d01b89c5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2C6-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,239 have no estimate.
https://portal.gdc.cancer.gov/files/df62f847-852f-4336-8c41-130187fcd48f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 68; copy number 1: 12,655; copy number 2: 39,865; copy number 3: 4,866; copy number 4: 394; copy number 5: 346; copy number 6: 69; copy number 7: 68; copy number 8: 35; copy number 9: 1; copy number 11: 6; copy number 14: 1; copy number 17: 2; copy number 19: 8.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:72,916,260–72,936,071, 2 genes: EMX1, AC012366.1.
- chr2:241,800,916–241,873,823, 6 genes (within-gene range 0–2): AC131097.1, AC131097.2, NEU4, AC131097.3, PDCD1, RTP5.
- chr4:1,550,284–1,550,572, 1 gene: AC147067.2.
- chr9:136,519,568–136,519,626, 1 gene (within-gene range 0–2): MIR4673.
- chr10:132,207,492–132,331,847, 1 gene: STK32C.
- chr11:3,189,546–3,223,131, 3 genes: AC108448.1, MRGPRG, MRGPRG-AS1.
- chr11:71,787,510–71,801,237, 1 gene (within-gene range 0–2): FAM86C1P.
- chr14:22,438,547–22,486,296, 19 genes (within-gene range 0–1): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52.
- chr15:25,172,635–25,213,729, 23 genes (within-gene range 0–2): SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24.
- chr15:78,759,206–78,811,464, 1 gene (within-gene range 0–2): ADAMTS7.
- chr16:1,911,475–1,918,415, 1 gene: HS3ST6.
- chr16:88,741,631–88,745,748, 2 genes (within-gene range 0–2): AC138028.5, AC138028.1.
- chr18:79,679,803–79,754,510, 2 genes (within-gene range 0–2): CTDP1, AC068473.2.
- chr20:63,520,765–63,537,376, 2 genes: PPDPF, PTK6.
- chr20:63,547,891–63,574,239, 2 genes: FNDC11, HELZ2.
- chr21:43,446,601–43,453,902, 1 gene: LINC00319.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 536 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,330,110–89,600,680, 2 genes, copy number 5: IGKV2-40, 5S_rRNA.
- chr3:177,010,719–177,767,379, 14 genes, copy number 6–8: MTND5P15, TBL1XR1, TBL1XR1-AS1, Y_RNA, RNU6-681P, LINC00501, ASS1P7, AC117465.1, LINC00578, RN7SKP52, AC026355.3, AC026355.1, AC026355.2, AC026355.4.
- chr3:178,272,932–178,844,429, 2 genes, copy number 5 (within-gene range 4–5): KCNMB2, AC117457.1.
- chr3:178,526,505–179,789,401, 24 genes, copy number 5–7 (within-gene range 4–7): KCNMB2-AS1, ZMAT3, Y_RNA, AC076966.2, PIK3CA, AC076966.1, KCNMB3, LRRFIP1P1, ZNF639, AC007823.1, MFN1, GNB4, AC007620.2, AC007620.3, AC007620.1, MTHFD2P7, ACTL6A, AC090425.3, AC090425.2, MRPL47, NDUFB5, AC090425.1, H3P13, USP13.
- chr3:181,952,343–192,917,856, 207 genes, copy number 5–14 (broad region; genes not listed).
- chr7:63,959,844–65,100,232, 65 genes, copy number 5–7 (broad region; genes not listed).
- chr7:68,020,235–68,319,676, 6 genes, copy number 5: AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3.
- chr11:69,294,151–70,436,584, 35 genes, copy number 5–7: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:95,089,846–95,497,553, 7 genes, copy number 6: ENDOD1, BUD13P1, AP000787.2, AP000787.1, SESN3, AP000787.3, AP001790.1.
- chr11:116,789,367–120,988,906, 148 genes, copy number 5–7 (within-gene range 1–7) (broad region; genes not listed).
- chr16:3,222,325–3,236,221, 1 gene, copy number 6 (within-gene range 2–6): ZNF200.
- chr16:30,267,553–30,335,374, 1 gene, copy number 7: SMG1P5.
- chr18:21,825,487–21,831,539, 3 genes, copy number 19 (within-gene range 3–19): MIR133A1HG, MIR133A1, MIR1-2.
- chr18:21,871,446–22,348,252, 14 genes, copy number 7–19: AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1.
- chr21:43,092,956–43,168,646, 2 genes, copy number 9–17 (within-gene range 1–17): U2AF1, AP001631.2.
- chr21:43,140,523–43,162,277, 2 genes, copy number 5–17: FRGCA, AP001631.1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 7 (within-gene range 7–13): LINC00313, AP001048.1.
- chr22:18,733,914–18,757,906, 1 gene, copy number 8: FAM230E.

Autosomal genes at a single copy (total copy number 1): 11,769. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
